Somatic mutation profile of tumor specimen PCProject_0212_T1_WES (aliquot PCProject_0212_T1_WES_1) from CMI case PCProject_0212, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.6 years (24,679 days).
Specimen PCProject_0212_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4bc4a29-b725-4513-8d21-2ea606312241.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0212_SALIVA (DNA), aliquot PCProject_0212_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d191999-fdb6-4416-88e2-20a2141d5e28

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Intron 2, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUL4B | c.2567G>T p.R856L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60684306, COSV60689455; called by muse, mutect2, varscan2
- DDX51 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371612714; called by muse, mutect2
- GRK6 | c.1622G>A p.G541D | Missense Mutation (SNP) | VAF 51/338 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs200510977, COSV62682627; called by muse, mutect2, varscan2
- GSN | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 66/436 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763998109, COSV100376782; called by muse, mutect2, varscan2
- PLEKHA4 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV99612451; called by muse, mutect2, varscan2
- PRRX1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs756917059, COSV53411375; called by muse, mutect2, varscan2
- RECQL4 | c.3460_3462del p.K1154del | In Frame Del (DEL) | VAF 42/277 reads (15%) | catalogued as rs1564787405; called by mutect2, pindel, varscan2
- SLC17A3 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756988365, COSV57759573; called by muse, mutect2, varscan2
- SLC4A1 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868742796, CM961313; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPEN | c.6732G>T p.Q2244H | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV101005397; called by muse, mutect2, varscan2
- TENM2 | c.2797C>T p.R933* (on ENST00000518659 / NM_001122679.2; = p.R701* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as rs1364686894; called by muse, mutect2, varscan2
- ZC3H13 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs1453685959; called by muse, mutect2, varscan2
- ATXN2L | c.412_413dup p.V139Rfs*2 | Frame Shift Ins (INS) | VAF 12/103 reads (12%) | called by mutect2, pindel, varscan2
- CELSR2 | c.2129del p.P710Lfs*10 | Frame Shift Del (DEL) | VAF 18/151 reads (12%) | called by mutect2, pindel, varscan2
- CTPS1 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2
- DNAJC16 | c.1595A>G p.N532S | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- LMF1 | c.68C>G p.S23W | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PPP3CA | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- RAC2 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 77/648 reads (12%) | called by muse, mutect2, varscan2
- RICTOR | c.1532A>G p.Y511C | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TMEM151A | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA13 | c.9204A>T p.V3068= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- ITSN2 | c.5091G>A p.L1697= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2
- KIFC3 | c.531C>T p.S177= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as rs148764340; called by muse, mutect2, varscan2
- KRTAP8-1 | c.141C>T p.N47= | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as rs368738418; called by muse, mutect2, varscan2
- LRP1 | c.9804C>T p.L3268= | Silent (SNP) | VAF 36/296 reads (12%) | catalogued as rs972258196; called by muse, mutect2, varscan2
- NOA1 | c.2010C>G p.R670= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV99950504; called by muse, mutect2
- UNC79 | c.3807C>T p.D1269= (on ENST00000393151 / NM_001346218.2; = p.D1092= on NM_020818.5) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs567253162, COSV56398104; called by muse, varscan2
- ZNF516 | c.1020C>T p.C340= | Silent (SNP) | VAF 31/716 reads (4%) | catalogued as rs1468507463; called by muse, mutect2
- DPYSL2 | c.-18T>C | 5'UTR (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- MACROH2A1 | c.478-137T>A | Intron (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- RDX | c.1091-231G>A | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as rs940415328; called by muse, mutect2
